Somatic mutation profile of tumor specimen 0DAL9N from CCDI case PBBKAW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.1 years (1,117 days).
Specimen 0DAL9N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d8c870a-c021-4061-97d5-d552b9931c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAL9O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a2b632c-1acf-4b12-9819-1837b18d814e

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303_2311dup p.S768_D770dup | In Frame Ins (INS) | VAF 176/594 reads (30%) | hotspot (GDC flag); catalogued as rs397517109; ClinVar: likely pathogenic / drug response; called by mutect2, varscan2
- H3C2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 346/892 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52517710, COSV52518111; called by mutect2, varscan2
- TP53 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 220/536 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 180/504 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, varscan2
- FBLN7 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 184/521 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs1052615164; called by muse, mutect2, varscan2
- CDH12 | c.1573T>C p.S525P | Missense Mutation (SNP) | VAF 535/1601 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- HDAC3 | c.32C>G p.P11R | Missense Mutation (SNP) | VAF 197/514 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- AFF4 | c.789G>A p.Q263= | Silent (SNP) | VAF 346/902 reads (38%) | called by muse, mutect2, varscan2
- RGPD4 | c.3939G>T p.G1313= | Silent (SNP) | VAF 68/294 reads (23%) | catalogued as COSV61746085; called by muse, mutect2, varscan2
- PORCN | c.947-20C>A | Intron (SNP) | VAF 89/235 reads (38%) | called by muse, mutect2, varscan2
- PTK2B | c.2733+15G>T | Intron (SNP) | VAF 277/782 reads (35%) | catalogued as rs781524974; called by muse, mutect2, varscan2
